Somatic mutation profile of tumor specimen 0DBW4C from CCDI case PBBLSG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.6 years (1,675 days).
Specimen 0DBW4C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d51e3405-77d9-4be2-9a53-b4826b6e9b00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBW3Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/557d7187-9757-4b40-9f61-8a85f1474c2f

The open-access MAF lists 25 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 7, 3'UTR 2, Frame Shift Del 2, Silent 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, varscan2
- DNAH10 | c.12905G>A p.R4302H (on ENST00000409039; = p.R4241H on NM_207437.3) | Missense Mutation (SNP) | VAF 131/299 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs775827104, COSV53018383; called by muse, mutect2, varscan2
- OR1S2 | c.616A>T p.M206L | Missense Mutation (SNP) | VAF 50/374 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs775290144, COSV56918768; called by muse, varscan2
- OR1S2 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 35/305 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.122); catalogued as rs772263847; called by muse, varscan2
- PLCE1 | c.3991G>A p.D1331N | Missense Mutation (SNP) | VAF 50/353 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as rs372685240; called by muse, mutect2, varscan2
- PTCH1 | c.900del p.D301Ifs*23 | Frame Shift Del (DEL) | VAF 92/114 reads (81%) | catalogued as COSV59466787; called by mutect2, varscan2
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by muse, mutect2, varscan2
- TFDP3 | c.390C>G p.C130W | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs772108089; called by muse, varscan2
- FARP1 | c.2524T>A p.S842T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.031); called by muse, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 44/748 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- NRAP | c.1843G>C p.V615L (on ENST00000359988 / NM_001322945.2; = p.V580L on NM_006175.4) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0.115); called by muse, varscan2
- USP17L4 | c.581A>T p.H194L | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); called by muse, mutect2
- WDR90 | c.3444_3445del p.G1149Rfs*57 | Frame Shift Del (DEL) | VAF 34/180 reads (19%) | called by mutect2, varscan2
- OR2G6 | c.435C>T p.A145= | Silent (SNP) | VAF 72/183 reads (39%) | catalogued as rs781744459, COSV58574078; called by muse, mutect2, varscan2
- ARFGEF2 | c.3222-64A>G | Intron (SNP) | VAF 10/76 reads (13%) | called by muse, varscan2
- AZGP1 | chr7:99976035 G>A | 5'Flank (SNP) | VAF 22/108 reads (20%) | catalogued as rs756746553; called by muse, varscan2
- CACNB4 | c.*95T>A | 3'UTR (SNP) | VAF 6/54 reads (11%) | called by muse, varscan2
- EEF1AKMT2 | c.292-25A>T | Intron (SNP) | VAF 11/105 reads (10%) | called by muse, mutect2, varscan2
- ERCC6L2 | c.471+29C>G | Intron (SNP) | VAF 14/106 reads (13%) | called by muse, varscan2
- FGFR1OP2 | c.396+73T>C | Intron (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99987084; called by muse, varscan2
- HNRNPD | c.854-23G>A | Intron (SNP) | VAF 11/220 reads (5%) | called by muse, mutect2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 4/14 reads (29%) | catalogued as COSV55814242; called by muse, mutect2
- PLGRKT | c.*95G>A | 3'UTR (SNP) | VAF 7/64 reads (11%) | called by muse, varscan2
- PPHLN1 | c.1126-179G>T | Intron (SNP) | VAF 7/58 reads (12%) | called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 8/42 reads (19%) | called by muse, varscan2
